Surgical pathology report (de-identified scan), TCGA case TCGA-GK-A6C7, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GK-A6C7-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, clear cell
renal cell 8312/3
Site R Kidney NOS
C64.9

W 5/24/13

NEW DOCUMENT:

Operative Procedure:

Laparoscopic right radical nephrectomy and liver biopsy

Specimen Received:

A: Right kidney and right adrenal gland

B: Liver, Biopsy (FS)

Final Pathologic Diagnosis:

A. Kidney and adrenal gland, right, radical nephrectomy:

Tumor histologic type: Clear cell renal cell carcinoma

Sarcomatoid features (%): None

Tumor size: 3.8 cm (greatest dimension)

Other dimensions: 3 x 2.5 cm

Macroscopic extent of tumor: Tumor is confined within renal parenchyma

Focality: Unifocal

Number of tumors: 1

Fuhrman grade: 2 of 4

Microscopic extent of tumor:

Perinephric fat invasion: No

Renal sinus invasion: No

Other: No

Renal vein involvement: No

Adrenal gland present: Yes

Involved by tumor: No

Other findings: Adrenal cortical adenoma (0.8 cm)

Cancer at resection margin: No

Pathologic findings in nonneoplastic kidney: None significant

Hilar lymph nodes present: No

Pathologic stage (2010): pT1a, pNX, pM-N/A

B. Liver, biopsy:

Hemangioma.

Frozen section diagnosis confirmed.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

The liver shows a circumscribed lesion composed of vascular spaces within fibrous stroma. The adjacent liver parenchyma shows no abnormalities (reticulin and trichrome stains performed). There is no iron deposition.

HI/PA Discrepancy		1/

[page 2 of 3]
Intraoperative Consult Diagnosis:

FSA: Right kidney and right adrenal gland:

8 cm tan-yellow mass, gross exam only.

F/S TAT: 7 mins.

FSB: Liver biopsy:

Hemangioma.

F/S TAT: 14 mins.

Gross Description:

Received in two containers labeled with the patient's name,

Part A is received in formalin and part B is received fresh for frozen section diagnosis.

Part A

Specimen components and dimensions: Right kidney, 12 x 7 x 4 cm. There is also a right adrenal gland that weighs 13 grams and measures 4 x 3 x 2 cm. There is a single 0.8 cm circumscribed nodule present.

Size, appearance, and location of tumor: Tumor size is 3.8 x 3 x 2.5 cm, yellow-tan lobulated with gray-tan discoloration in the middle.

Renal capsule/renal sinus: The tumor is 0.2 cm from the renal capsule and 0.3 cm from the renal sinus.

Renal vein: The tumor does not invade the renal vein.

Lymph nodes (size, number, & location): Probable ten lymph nodes with size ranging from 1.2 to 0.4 cm are found in the hilum.

Other findings: No other findings.

Blocks submitted:

- A1 ureter and vascular margin;
- A2-3 tumor to capsule;
- A4-5 tumor to renal sinus;
- A6-7 tumor to hilum;
- A8 uninvolved renal parenchyma;
- A9 adrenal;
- A10 two possible lymph nodes;
- A11 two possible lymph nodes;
- A12 one possible lymph node;
- A13 two possible lymph nodes;
- A14-16 three random sections of the perihilar fat.

Observation: The perihilar fat weighs 20 grams.

Part B is received fresh and additionally labeled "liver biopsy." It is submitted for frozen section diagnosis. The remainder of the tissue is submitted in cassette B1. Also in the same container there is a brown-tan soft tissue that measures 3 x 2 x 1 cm. Cut sections reveal a solid lesion measuring 1.8 cm in greatest dimension. Representative sections are submitted in cassettes B2 and B3.

[page 3 of 3]
Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age: , Gender: F

Source: NCI Genomic Data Commons file 36cc4aef-16eb-4426-95a1-7248e36c9151 (TCGA-GK-A6C7.FAC39368-68AC-4426-BAFF-43E0BBFDA701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).